Gene-level copy-number profile of tumor specimen TCGA-CG-5732-01A from TCGA case TCGA-CG-5732, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 66.7 years (24,379 days).
Specimen TCGA-CG-5732-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.25698f90-a675-46ba-9d89-b5912d37f681.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CG-5732-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a823422a-ae2b-4c3a-a222-14a1f7ee328b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 13,144; copy number 2: 39,126; copy number 3: 6,383; copy number 4: 692; copy number 5: 118; copy number 6: 15; copy number 7: 238; copy number 8: 59; copy number 9: 42.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CG-5732-01A-11D-1599-01): tumor purity 0.58, ploidy 2.03, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 472 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:71,445,616–73,201,973, 36 genes, copy number 7: AC145141.1, BDP1, AC138832.1, HMGN1P12, MCCC2, CARTPT, AC143336.1, AC025774.1, MAP1B, MIR4803, MRPS27, RN7SL153P, PTCD2, AC093278.1, YBX1P5, AC093278.2, ZNF366, LINC02056, AC063979.1, RPL7P22, H2BL1P, Y_RNA, AC035140.1, TNPO1, MIR4804, RPL35AP13, AC008972.1, AC008972.2, FCHO2, AC020893.1, CHP1P1, TMEM171, AC116345.3, AC116345.2, TMEM174, AC116345.4.
- chr5:74,777,574–74,866,966, 1 gene, copy number 5 (within-gene range 2–5): FAM169A.
- chr5:74,798,994–76,981,158, 53 genes, copy number 5–8: AC093214.1, AC010501.2, AC010501.1, AC116337.4, AC116337.3, AC116337.1, AC116337.2, RPL27AP5, AC093259.1, GCNT4, ANKRD31, SUMO2P5, AC008897.2, HMGCR, CERT1, AC008897.3, AC008897.1, POLK, RNU7-175P, AC010245.1, AC010245.2, ANKDD1B, POC5, RNU6-680P, SLC25A5P9, AC108120.3, AC108120.2, BIN2P2, AC108120.1, SAP18P1, AC026774.2, AC026774.1, SV2C, RNA5SP186, AC113404.2, AC113404.3, HMGN2P4, PDCD5P2, AC113404.1, SNRPCP2, IQGAP2, AC112173.1, AC026725.1, F2RL2, AC025188.1, AC025188.2, AC025188.3, F2R, F2RL1, RN7SL208P, S100Z, RNU6ATAC36P, CRHBP.
- chr6:118,452,469–118,454,992, 1 gene, copy number 6: AL589993.1.
- chr6:118,501,430–118,502,906, 1 gene, copy number 6: BRD7P3.
- chr6:141,486,141–142,957,945, 15 genes, copy number 5: RN7SKP106, RPS3AP23, NMBR, AL589674.1, NMBR-AS1, GJE1, VTA1, AL360007.1, ADGRG6, AL359313.1, AL355337.1, AL023584.1, HIVEP2, AL023584.2, AL355304.1.
- chr6:147,508,690–147,737,547, 1 gene, copy number 6 (within-gene range 4–6): SAMD5.
- chr11:27,978,669–28,108,156, 3 genes, copy number 5 (within-gene range 2–5): AC090159.1, KIF18A, MIR610.
- chr15:89,201,091–90,314,499, 60 genes, copy number 5: AC124068.1, RLBP1, FANCI, POLG, MIR6766, AC124068.2, AC133637.1, AC133637.2, MIR9-3HG, MIR9-3, RHCG, LINC00928, AC013391.3, AC013391.2, TICRR, AC013391.1, KIF7, PLIN1, PEX11A, RPL36AP43, WDR93, AC079075.1, RNU6-132P, MESP1, MRPL15P1, MESP2, ANPEP, AP3S2, ARPIN-AP3S2, MIR5094, AC027176.2, MIR5009, RNU6-1111P, ARPIN, RNU7-111P, AC027176.1, AC027176.3, ZNF710, MIR3174, AC087284.1, ZNF710-AS1, U7, IDH2, IDH2-DT, SEMA4B, RN7SL346P, RPS12P26, CIB1, GDPGP1, AC091167.7, TTLL13P, AC091167.2, NGRN, AC091167.6, AC091167.1, AC091167.3, AC091167.5, AC091167.4, GOLGA2P8, RN7SL736P.
- chr20:43,304,555–55,684,915, 301 genes, copy number 6–9 (within-gene range 4–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 10,723. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
